CCDI case PBBTVN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b20968f1-abe3-43ce-8338-7ab77f5a6458

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Myeloid sarcoma: ICD-O-3 morphology code: 9930/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 2.1 years (779 days).

Biospecimens (3 samples)
- Sample 0DGWO8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGWOE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGWOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
